Somatic mutation profile of tumor specimen C3L-02606-02 (aliquot CPT0124500006_1) from CPTAC case C3L-02606, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.9 years (25,148 days).
Specimen C3L-02606-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 474e3fe5-056f-45b0-8d77-bf2ea7a7ffaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02606-31 (Blood Derived Normal), aliquot CPT0124540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1776b1cd-f74f-4cde-bac1-a3d016c9b557

The open-access MAF lists 69 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Intron 7, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 127/863 reads (15%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 85/655 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 105/709 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022dup p.N342Efs*2 | Frame Shift Ins (INS) | VAF 50/314 reads (16%) | catalogued as rs746174250; called by mutect2, varscan2
- CCNA1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 81/737 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750419153, COSV55222625; called by muse, mutect2, varscan2
- CCT2 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 27/428 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs749401932, COSV54739289; called by muse, mutect2
- CDH24 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs764282796, COSV52974166; called by muse, mutect2, varscan2
- CHST1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208095218, COSV57321999; called by muse, mutect2
- CYP11A1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 33/344 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs763099365, COSV51430559; called by muse, mutect2
- DOCK9 | c.3190A>T p.K1064* (on ENST00000376460 / NM_001366676.2; = p.K1065* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/206 reads (13%) | catalogued as COSV59636152; called by muse, mutect2, varscan2
- EFNB1 | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 114/793 reads (14%) | catalogued as CX084344; called by muse, mutect2, varscan2
- EIF4G2 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 130/1099 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.024); catalogued as COSV101150826; called by muse, mutect2, varscan2
- GGH | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as rs554949020, COSV99479016; called by muse, mutect2, varscan2
- GIPR | c.385-1G>C p.X129_splice | Splice Site (SNP) | VAF 64/1378 reads (5%) | catalogued as rs747744657; called by muse, mutect2
- GYS2 | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 109/764 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs148461282; called by muse, mutect2, varscan2
- LRFN5 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV53242887; called by muse, mutect2
- LRRTM1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs1168813756, COSV99703402; called by muse, mutect2, varscan2
- PCDHA3 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 86/717 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.123); catalogued as rs1554121379, COSV65366871; called by muse, mutect2, varscan2
- PCDHGA6 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 83/603 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs371346343, COSV54018804; called by muse, mutect2, varscan2
- POTEJ | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 287/1661 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as rs761434672; called by muse, mutect2, varscan2
- RNF103 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 77/415 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1262913118, COSV52896064; called by muse, mutect2, varscan2
- SETBP1 | c.3961C>T p.R1321C | Missense Mutation (SNP) | VAF 49/705 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767301100; ClinVar: likely benign; called by muse, mutect2
- SPTA1 | c.3743G>A p.R1248Q | Missense Mutation (SNP) | VAF 73/494 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs568044940, COSV63753987; called by muse, mutect2, varscan2
- TFR2 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 124/932 reads (13%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.862); catalogued as rs920217192; called by muse, mutect2, varscan2
- TTN | c.59080G>A p.E19694K (on ENST00000591111; = p.E12270K on NM_003319.4) | Missense Mutation (SNP) | VAF 164/905 reads (18%) | PolyPhen probably damaging (0.994); catalogued as rs773791222, COSV60221006; called by muse, mutect2, varscan2
- UNC5C | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.594); catalogued as rs775796452, COSV71661666; called by muse, mutect2
- VLDLR | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 113/840 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769791140; called by muse, mutect2, varscan2
- ZNF433 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1204422588, COSV61398493; called by muse, mutect2, varscan2
- ACE | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 56/440 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CSRNP2 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 41/674 reads (6%) | called by muse, mutect2
- DYNC2H1 | c.11058G>T p.L3686F | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EFCAB3 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ETV4 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARS2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 156/1075 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAT2 | c.3197A>C p.E1066A | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2
- FOXI1 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2
- KMT2D | c.1298_1328del p.P433Hfs*487 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- OR5AP2 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 48/441 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDHA5 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 60/704 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); called by muse, mutect2
- PCF11 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 70/767 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNF19A | c.1683G>A p.R561= | Splice Region (SNP) | VAF 47/452 reads (10%) | called by muse, varscan2
- TEDC2 | c.197-2A>G p.X66_splice | Splice Site (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- TRIM56 | c.1129_1131del p.K377del | In Frame Del (DEL) | VAF 22/258 reads (9%) | called by mutect2, pindel
- TRIM71 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- UBAP1 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UMODL1 | c.3547del p.T1183Hfs*5 (on ENST00000408910 / NM_001004416.2; = p.T1311Hfs*5 on NM_173568.3) | Frame Shift Del (DEL) | VAF 53/377 reads (14%) | called by mutect2, pindel, varscan2
- ZFP36 | c.124G>A p.G42R (on ENST00000594442; = p.G36R on NM_003407.5) | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- BRWD3 | c.1023G>C p.V341= | Silent (SNP) | VAF 30/391 reads (8%) | called by muse, mutect2
- CACNA1I | c.5649C>T p.G1883= | Silent (SNP) | VAF 39/316 reads (12%) | called by muse, mutect2, varscan2
- CDH7 | c.531G>A p.A177= | Silent (SNP) | VAF 66/703 reads (9%) | catalogued as rs567500655, COSV59881966; called by muse, mutect2
- COL6A5 | c.1665C>T p.S555= | Silent (SNP) | VAF 49/730 reads (7%) | catalogued as COSV55196411; called by muse, mutect2
- CYP2S1 | c.636C>G p.V212= | Silent (SNP) | VAF 28/574 reads (5%) | called by muse, mutect2
- ERFE | c.207C>T p.T69= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs970950289, COSV60137478; called by muse, mutect2, varscan2
- GRIP2 | c.1392C>T p.P464= (on ENST00000619221; = p.P367= on NM_001080423.4) | Silent (SNP) | VAF 41/311 reads (13%) | catalogued as rs892714157; called by muse, mutect2, varscan2
- KSR2 | c.1584G>A p.T528= | Silent (SNP) | VAF 48/478 reads (10%) | catalogued as rs753143776, COSV56676969; called by muse, mutect2
- LMX1A | c.174G>A p.Q58= | Silent (SNP) | VAF 36/873 reads (4%) | called by muse, mutect2
- PCDH8 | c.489C>T p.D163= | Silent (SNP) | VAF 55/466 reads (12%) | catalogued as COSV58810931; called by muse, mutect2, varscan2
- RGS9 | c.357C>T p.T119= | Silent (SNP) | VAF 44/1108 reads (4%) | catalogued as rs747170529; called by muse, mutect2
- TMC3 | c.141G>A p.P47= | Silent (SNP) | VAF 30/498 reads (6%) | catalogued as rs375088581; called by muse, mutect2
- ZNF148 | c.2043T>C p.G681= | Silent (SNP) | VAF 56/526 reads (11%) | called by muse, mutect2, varscan2
- ATPSCKMT | chr5:10249897 del TA | 5'Flank (DEL) | VAF 43/165 reads (26%) | catalogued as rs1561039450; called by mutect2, varscan2*
- CIDEA | c.38+138C>T | Intron (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- EYS | c.1767-6583G>A | Intron (SNP) | VAF 88/817 reads (11%) | catalogued as rs767825310; called by muse, mutect2, varscan2
- FLNB | c.542-237A>G | Intron (SNP) | VAF 59/368 reads (16%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10594C>T | Intron (SNP) | VAF 34/432 reads (8%) | catalogued as rs1261477358, COSV57130946; called by muse, mutect2
- NAB2 | c.-33G>A | 5'UTR (SNP) | VAF 50/754 reads (7%) | catalogued as rs1351301604; called by muse, mutect2
- TTYH1 | c.126+1193C>G | Intron (SNP) | VAF 163/654 reads (25%) | called by muse, mutect2, varscan2
- UBE2D3 | c.25-1883C>G | Intron (SNP) | VAF 55/247 reads (22%) | called by muse, mutect2, varscan2
- VGLL4 | c.64+31577C>T | Intron (SNP) | VAF 30/195 reads (15%) | catalogued as rs751713418; called by muse, mutect2
